Somatic mutation profile of tumor specimen C3N-02726-01 (aliquot CPT0176400006) from CPTAC case C3N-02726, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 53.6 years (19,566 days).
Specimen C3N-02726-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d990d790-08f9-4a06-8835-6b8f2c116761.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02726-71 (Blood Derived Normal), aliquot CPT0176520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d3fe524-d264-4c25-897b-98c46b2117d4

The open-access MAF lists 69 somatic variants for this specimen: 55 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 9, Nonsense Mutation 7, Splice Site 3, Frame Shift Del 3, Intron 2, RNA 2, Translation Start Site 1, In Frame Del 1, Frame Shift Ins 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+2T>C p.X155_splice | Splice Site (SNP) | VAF 38/218 reads (17%) | hotspot (GDC flag); catalogued as rs5030814, CS961707, COSV56543181, COSV56545468, COSV56553134; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ARL10 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 75/436 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs898775768; called by muse, mutect2, varscan2
- COL6A3 | c.5149G>A p.A1717T | Missense Mutation (SNP) | VAF 72/470 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs376135795, COSV55088006; called by muse, mutect2, varscan2
- DENND3 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.952); catalogued as rs753853397; called by muse, mutect2, varscan2
- GDA | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 85/460 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as rs560911277; called by muse, mutect2, varscan2
- GPRC5B | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56025948; called by muse, mutect2, varscan2
- IVD | c.1219del p.A407Lfs*6 (on ENST00000651168; = p.A404Lfs*6 on NM_002225.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 60/543 reads (11%) | catalogued as COSV51101214; called by pindel, varscan2*
- KIF1C | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs1320673365; called by muse, mutect2, varscan2
- MYOM2 | c.2911A>C p.N971H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs373388952; called by muse, mutect2, varscan2
- NTRK2 | c.2251A>G p.K751E (on ENST00000323115 / NM_001369534.1; = p.K767E on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52883963; called by muse, mutect2, varscan2
- OR2AK2 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.39); catalogued as COSV63563838, COSV99057401; called by muse, mutect2, varscan2
- OR5B17 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs562004519, COSV62160736; called by muse, mutect2, varscan2
- PBRM1 | c.1182del p.S395Vfs*9 | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | catalogued as COSV56270679; called by mutect2, pindel, varscan2
- PEAK1 | c.1796A>G p.N599S | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56931871; called by muse, mutect2, varscan2
- PROX1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54779792; called by muse, mutect2, varscan2
- SCARA5 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs775439485, COSV57278189; called by muse, mutect2, varscan2
- SLC46A2 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100953488; called by muse, mutect2, varscan2
- SRP72 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 14/155 reads (9%) | catalogued as rs146473599; called by muse, mutect2
- THSD7A | c.2120del p.C707Sfs*55 | Frame Shift Del (DEL) | VAF 20/178 reads (11%) | catalogued as COSV101448688; called by mutect2, pindel, varscan2
- TUBGCP2 | c.1829T>G p.L610R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53306334; called by muse, mutect2, varscan2
- UACA | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.288); catalogued as rs370665811, COSV99060932; called by muse, mutect2, varscan2
- ZFYVE26 | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61327668; called by muse, mutect2, varscan2
- ABCC5 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP3 | c.261C>A p.N87K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- COG1 | c.2510+1G>A p.X837_splice | Splice Site (SNP) | VAF 72/491 reads (15%) | called by muse, mutect2, varscan2
- CTR9 | c.37_42del p.T13_D14del | In Frame Del (DEL) | VAF 35/282 reads (12%) | called by mutect2, pindel, varscan2
- DNAH2 | c.3932T>C p.L1311P | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- DSEL | c.2656A>C p.S886R | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- DST | c.19712G>T p.S6571I (on ENST00000361203 / NM_001374722.1; = p.S4268I on NM_015548.5) | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC1H1 | c.9814G>A p.A3272T | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, varscan2
- ECH1 | c.524-4C>G | Splice Region (SNP) | VAF 45/242 reads (19%) | called by muse, mutect2, varscan2
- EID2 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ERBB4 | c.2216C>G p.P739R | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ETAA1 | c.2536G>C p.D846H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.939); called by muse, varscan2
- EVPL | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 46/264 reads (17%) | called by muse, mutect2, varscan2
- KIAA2012 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 32/161 reads (20%) | called by muse, mutect2, varscan2
- KIF20B | c.2544A>T p.K848N (on ENST00000371728 / NM_001284259.2; = p.K808N on NM_016195.4) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NKPD1 | c.661+1del p.X221_splice | Splice Site (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- PDHA1 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- PDILT | c.1546G>T p.V516L | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLB1 | c.811A>G p.S271G | Missense Mutation (SNP) | VAF 46/341 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP4R3A | c.156A>T p.L52F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRIM2 | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2
- PSMD1 | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- RBM44 | c.681T>G p.I227M (on ENST00000611254; = p.I861M on NM_001080504.2) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SCD | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 58/324 reads (18%) | called by muse, mutect2, varscan2
- SETD2 | c.7621A>T p.K2541* | Nonsense Mutation (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- SLC2A12 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC39A6 | c.1256A>T p.D419V | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC49A3 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- TNRC6A | c.3979dup p.R1327Kfs*30 | Frame Shift Ins (INS) | VAF 29/171 reads (17%) | called by mutect2, pindel, varscan2
- TTC37 | c.3931A>G p.I1311V | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZGPAT | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZNF572 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ZNF575 | c.30A>G p.I10M | Missense Mutation (SNP) | VAF 71/462 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ADRA1A | c.1098C>T p.A366= | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as rs373906244; called by muse, mutect2, varscan2
- DEAF1 | c.588T>G p.P196= | Silent (SNP) | VAF 89/604 reads (15%) | called by muse, mutect2, varscan2
- FUT7 | c.750T>C p.T250= | Silent (SNP) | VAF 89/535 reads (17%) | called by muse, mutect2, varscan2
- KLHL30 | c.1557C>T p.G519= | Silent (SNP) | VAF 81/502 reads (16%) | catalogued as rs1193070255, COSV100014045, COSV59975838; called by muse, mutect2, varscan2
- MINDY4B | c.438C>A p.A146= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as COSV67404196; called by muse, mutect2, varscan2
- NOL8 | c.2970T>C p.Y990= | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- NUP62 | c.255A>G p.G85= | Silent (SNP) | VAF 175/972 reads (18%) | called by muse, mutect2, varscan2
- PADI6 | c.1032A>G p.A344= | Silent (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- SLC39A2 | c.327C>A p.I109= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- CD33 | chr19:51225076 del T | 5'Flank (DEL) | VAF 47/391 reads (12%) | catalogued as COSV99220573; called by mutect2, pindel, varscan2
- LINC00905 | n.1004C>A | RNA (SNP) | VAF 74/371 reads (20%) | called by muse, mutect2, varscan2
- PON3 | c.495-37_495-34del | Intron (DEL) | VAF 38/178 reads (21%) | called by mutect2, pindel, varscan2
- RBM39 | c.102-2824T>C | Intron (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- ZNF252P | n.1694G>A | RNA (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
